Somatic mutation profile of tumor specimen TCGA-3B-A9HV-01A (aliquot TCGA-3B-A9HV-01A-11D-A38Z-09) from TCGA case TCGA-3B-A9HV, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 48.3 years (17,638 days).
Specimen TCGA-3B-A9HV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f377da91-7a24-4e81-9e80-03427a582316.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3B-A9HV-10A (Blood Derived Normal), aliquot TCGA-3B-A9HV-10A-01D-A38Z-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35b6a00e-5a11-4926-9295-fd492c62cc4a

The open-access MAF lists 44 somatic variants for this specimen: 36 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 7, Frame Shift Del 2, Splice Site 2, In Frame Del 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.581T>G p.L194R | Missense Mutation (SNP) | VAF 36/78 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519998, COSV52663681, COSV52677924, COSV52679257, COSV52713187; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AC100868.1 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV51844596, COSV99226405; called by muse, mutect2, varscan2
- ACSF3 | c.1187G>A p.R396K | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100441445, COSV58077627; called by muse, mutect2, varscan2
- ADAM30 | c.1852T>A p.C618S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1422696007, COSV101023919; called by muse, mutect2, varscan2
- ALOX12 | c.1766T>A p.L589H | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99278230; called by muse, mutect2, varscan2
- ASPN | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV100978648; called by muse, mutect2, varscan2
- C14orf119 | c.188C>G p.A63G | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV52973932, COSV99399900; called by muse, mutect2, varscan2
- CFAP46 | c.5774C>T p.T1925M | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.066); catalogued as rs751307434, COSV99585190; called by muse, mutect2, varscan2
- CKS2 | c.206T>G p.F69C | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100068868; called by muse, mutect2, varscan2
- DNAH2 | c.11615G>A p.G3872D | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66723452; called by muse, mutect2, varscan2
- ERAS | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV54432708, COSV99504862; called by muse, mutect2, varscan2
- ETV5 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 39/83 reads (47%) | catalogued as COSV100112434; called by muse, mutect2, varscan2
- FCRL2 | c.754A>T p.T252S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.241); catalogued as COSV100829955; called by muse, mutect2, varscan2
- FLAD1 | c.1646G>T p.S549I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV99422733; called by muse, mutect2
- FOXN3 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV54309841, COSV99726829; called by muse, mutect2, varscan2
- GRIA1 | c.88T>G p.L30V | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as COSV99600939; called by muse, mutect2, varscan2
- H1-2 | c.89del p.G30Vfs*33 | Frame Shift Del (DEL) | VAF 44/111 reads (40%) | catalogued as COSV59190043; called by mutect2, pindel, varscan2
- ICE2 | c.2119+1G>A p.X707_splice | Splice Site (SNP) | VAF 16/60 reads (27%) | catalogued as rs776463474, COSV55034368; called by muse, mutect2, varscan2
- KCNU1 | c.1651C>G p.H551D | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.136); catalogued as COSV101299326; called by muse, mutect2
- NTRK1 | c.1060G>A p.V354I | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as rs201035170, COSV100693573; called by muse, mutect2, varscan2
- PREX1 | c.1882-1G>T p.X628_splice | Splice Site (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100906585; called by mutect2, varscan2
- RP1 | c.2844C>A p.S948R | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV99608151; called by muse, mutect2, varscan2
- SLC12A3 | c.2239C>G p.Q747E | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.101); catalogued as CM114839, COSV99344466; called by muse, mutect2
- TBC1D5 | c.2062C>A p.Q688K | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.015); catalogued as COSV53766492; called by muse, mutect2, varscan2
- TBCB | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs866639426, COSV99387550; called by muse, mutect2, varscan2
- TIAM1 | c.678T>G p.C226W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV99736911; called by muse, mutect2, varscan2
- TP53 | c.672G>T p.E224D | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs267605076, CS100446, COSV52678333, COSV52681634, COSV52721244; called by muse, mutect2, varscan2
- TTC30B | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV101282801; called by muse, mutect2, varscan2
- UBE3C | c.1771A>C p.I591L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.024); catalogued as COSV100780017; called by muse, mutect2, varscan2
- USF3 | c.3355A>G p.N1119D | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.341); catalogued as rs182770151, COSV100325518; called by muse, varscan2
- WIF1 | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as rs575603863, COSV99683125; called by muse, varscan2
- ZFX | c.1191A>C p.K397N | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100457879; called by muse, mutect2, varscan2
- AC242842.3 | c.427G>C p.D143H | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- ADAD1 | c.1356_1359del p.H453Lfs*3 | Frame Shift Del (DEL) | VAF 28/67 reads (42%) | called by mutect2, pindel, varscan2
- MUC16 | c.7418_7435del p.R2473_V2479delinsI | In Frame Del (DEL) | VAF 16/30 reads (53%) | called by mutect2, varscan2
- ZNF48 | c.1766_1771del p.H589_Q590del | In Frame Del (DEL) | VAF 9/26 reads (35%) | called by mutect2, pindel, varscan2
- ADAM7 | c.864T>C p.V288= | Silent (SNP) | VAF 46/50 reads (92%) | catalogued as COSV99444381; called by muse, mutect2, varscan2
- AMPD1 | c.2208C>T p.D736= | Silent (SNP) | VAF 7/85 reads (8%) | catalogued as COSV100815120; called by muse, mutect2
- COL11A2 | c.1854T>A p.P618= (on ENST00000341947 / NM_080680.3; = p.P511= on NM_080679.2) | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV100554277, COSV100554582; called by muse, mutect2, varscan2
- SHISA3 | c.429A>C p.T143= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV100069881; called by muse, mutect2, varscan2
- TIMM44 | c.522G>A p.A174= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs752329160, COSV99564213; called by muse, mutect2, varscan2
- UGT3A1 | c.1071C>G p.L357= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV99955032; called by muse, mutect2, varscan2
- ZNF630 | c.120C>A p.T40= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV99332478; called by muse, mutect2, varscan2
- CRELD2 | c.593-307G>A | Intron (SNP) | VAF 17/69 reads (25%) | catalogued as rs368043307; called by muse, mutect2, varscan2
